Gene-level copy-number profile of tumor specimen TCGA-33-4566-01A from TCGA case TCGA-33-4566, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 40.1 years (14,643 days).
Specimen TCGA-33-4566-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.17020a37-e90a-4d47-931b-cd141919f30b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-33-4566-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5f7d5bb4-b4ba-4d86-b0a0-a7839e01ecc8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 68; copy number 1: 4,578; copy number 2: 27,677; copy number 3: 20,098; copy number 4: 5,609; copy number 5: 1,071; copy number 6: 199; copy number 7: 182; copy number 8: 3; copy number 9: 328.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-33-4566-01A-01D-1439-01): tumor purity 0.53, ploidy 2.55, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–22,455,740, 60 genes: FOCAD, FOCAD-AS1, MIR491, SNORA30B, HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr16:78,793,584–79,017,429, 8 genes: AC009141.1, RPS3P7, AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2, AC009145.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,783 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:215,436,253–215,941,719, 11 genes, copy number 5: AC012462.3, AC012462.1, AC012462.2, AC012668.2, AC012668.3, AC012668.1, LINC00607, LINC01614, AC093850.1, AC122136.1, AC093382.1.
- chr5:14,143,342–45,895,970, 456 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr7:70,972–95,683, 2 genes, copy number 5 (within-gene range 3–5): AC093627.1, AC093627.6.
- chr8:107,499,773–109,565,996, 23 genes, copy number 5: AC091010.1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9.
- chr8:125,648,327–130,017,129, 63 genes, copy number 6–9 (broad region; genes not listed).
- chr9:93,576,584–94,603,990, 28 genes, copy number 5 (within-gene range 3–5): PHF2, MIR548AU, AL442224.1, MIR4291, BARX1, BARX1-DT, PTPDC1, CYCSP24, AL360020.1, AL158152.1, MIRLET7A1HG, MIRLET7A1, MIRLET7F1, LINC02603, MIRLET7D, ZNF169, VDAC1P11, NUTM2F, AL691447.2, AL691447.1, PTMAP12, MFSD14B, YRDCP1, AL358232.2, AL358232.1, RNU6-669P, PCAT7, FBP2.
- chr12:66,767–34,249,958, 850 genes, copy number 5–9 (broad region; genes not listed).
- chr16:30,704,067–30,745,169, 1 gene, copy number 7 (within-gene range 2–7): AC106886.5.
- chr16:30,740,642–31,453,493, 61 genes, copy number 7 (broad region; genes not listed).
- chr18:47,390–2,489,426, 48 genes, copy number 7: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1, AP005230.1, AIDAP3.
- chr19:32,691,961–33,815,763, 34 genes, copy number 7 (within-gene range 4–7): NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88, LRP3, AC008738.1, AC008738.7, SLC7A10, AC008738.4, AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG, PEPD, AC010485.1, RPL21P131, CHST8, KCTD15.
- chr20:56,459,428–62,873,076, 161 genes, copy number 6 (broad region; genes not listed).
- chr21:15,263,421–17,894,485, 44 genes, copy number 5: AF130248.1, AF246928.1, AJ009632.2, CYCSP42, AJ009632.1, RNU6-1326P, RAD23BP3, USP25, RBPMSLP, MIR99AHG, RNU6-426P, VDAC2P1, RPS26P5, SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1, AF212831.1, NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1, AP000432.2, C21orf91-OT1, C21orf91, AL109761.1, CHODL-AS1, RPL37P3.
- chr21:18,022,370–18,114,904, 1 gene, copy number 5 (within-gene range 4–5): AF130417.1.

Autosomal genes at a single copy (total copy number 1): 3,788. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
